Somatic mutation profile of tumor specimen TCGA-AN-A04C-01A (aliquot TCGA-AN-A04C-01A-21W-A050-09) from TCGA case TCGA-AN-A04C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.6 years (18,851 days).
Specimen TCGA-AN-A04C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c52b7af4-adeb-456e-8312-cc67d1cc6112.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A04C-10A (Blood Derived Normal), aliquot TCGA-AN-A04C-10A-01D-A047-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83c9cede-3950-4d6d-9a6a-8052c3ee8d70

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 18, Frame Shift Ins 4, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 87/132 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDOB | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as COSV66397903; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 13/118 reads (11%) | catalogued as rs3215969; called by mutect2, varscan2
- ARR3 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs901050347, COSV52103427; called by muse, mutect2, varscan2
- BCAS1 | c.663A>C p.Q221H | Missense Mutation (SNP) | VAF 76/426 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV65086307; called by muse, mutect2, varscan2
- BGN | c.262A>T p.I88F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100525291; called by muse, mutect2
- CNTN4 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100639763, COSV100639842; called by muse, mutect2, varscan2
- CNTNAP5 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 51/291 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV70487540; called by muse, mutect2, varscan2
- CSMD1 | c.6595G>A p.D2199N (on ENST00000520002; = p.D2198N on NM_033225.6) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1339389309, COSV59299379; called by muse, mutect2
- CXCR3 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV65461751; called by muse, mutect2, varscan2
- DCC | c.1675C>A p.Q559K | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.326); catalogued as COSV59104434; called by muse, mutect2, varscan2
- DOCK11 | c.2818A>G p.T940A | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52239535; called by muse, mutect2, varscan2
- ENPP1 | c.1946-1G>C p.X649_splice | Splice Site (SNP) | VAF 340/475 reads (72%) | catalogued as COSV62932533; called by muse, mutect2, varscan2
- EYA3 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 16/409 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100870299; called by muse, mutect2
- FBXO21 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV57972986; called by muse, mutect2, varscan2
- FMNL3 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 181/513 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV53302376; called by muse, mutect2, varscan2
- GABRR1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs185436805; called by muse, mutect2, varscan2
- GCC2 | c.4710A>C p.K1570N | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100565661; called by muse, mutect2
- GIMAP1 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56188279; called by muse, mutect2, varscan2
- GJA8 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs149146673; ClinVar: benign; called by muse, mutect2, varscan2
- GRIK5 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs778914367, COSV53474560; called by muse, mutect2, varscan2
- GRIN2C | c.506C>G p.T169S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); catalogued as COSV53112777; called by muse, mutect2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2
- HCRTR2 | c.32dup p.C12Lfs*12 | Frame Shift Ins (INS) | VAF 15/142 reads (11%) | catalogued as rs755844571; called by mutect2, varscan2
- IGHV3-16 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs1555446162; called by muse, mutect2
- KAT8 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV54896800; called by muse, mutect2, varscan2
- KCNB1 | c.2018A>G p.K673R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.286); catalogued as COSV65568447; called by muse, mutect2, varscan2
- KCND1 | c.248T>G p.F83C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV54414267; called by muse, mutect2, varscan2
- KMT2D | c.10876C>T p.R3626W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766696812, COSV56443488; called by muse, mutect2, varscan2
- LRP2 | c.11899G>T p.E3967* | Nonsense Mutation (SNP) | VAF 38/599 reads (6%) | catalogued as COSV55541769; called by muse, mutect2
- LRRC41 | c.2288C>A p.A763D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.106); catalogued as COSV58440230, COSV58442772; called by muse, mutect2, varscan2
- MAP3K13 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs548832664, COSV53989443; called by muse, mutect2, varscan2
- MTHFD1 | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 46/300 reads (15%) | catalogued as COSV53700649; called by muse, mutect2, varscan2
- MYO7A | c.6439G>A p.D2147N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV60017640; called by muse, mutect2, varscan2
- NOBOX | c.487dup p.R163Pfs*48 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs754069719; called by mutect2, varscan2
- NOMO1 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99814915; called by mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 49/384 reads (13%) | catalogued as rs754860965; called by mutect2, varscan2
- PCDH9 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV60553431; called by muse, mutect2, varscan2
- PIK3CA | c.1886C>G p.S629C | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV55931727; called by muse, mutect2, varscan2
- PLA2G2F | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs370472527; called by muse, mutect2, varscan2
- POLR2B | c.32A>T p.D11V | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV58900655; called by muse, mutect2, varscan2
- PUS1 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); catalogued as rs986682392, COSV59035576; called by muse, mutect2, varscan2
- RASAL3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100640338; called by muse, mutect2
- RCN1 | c.883A>T p.N295Y | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV50014633; called by muse, mutect2, varscan2
- REL | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV99692442; called by muse, mutect2, varscan2
- RFX6 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60588125; called by muse, mutect2
- RNF20 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1189305225, COSV66661159; called by muse, mutect2, varscan2
- RPL13A | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV52619238, COSV52619565; called by muse, mutect2, varscan2
- SALL4 | c.1567G>A p.G523R | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs113920122, COSV99409552; called by muse, mutect2
- SETDB1 | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 84/537 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs751371356, COSV54977084; called by muse, mutect2, varscan2
- TENT4A | c.896A>G p.D299G | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50095937; called by muse, mutect2, varscan2
- TMEM132B | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV54753244, COSV54754646; called by muse, mutect2, varscan2
- TRAPPC10 | c.1724G>A p.G575D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.113); catalogued as COSV52377686; called by muse, mutect2, varscan2
- UPF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs979564728, COSV62660845; called by muse, mutect2, varscan2
- VPS18 | c.2168A>G p.Y723C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367776525; called by muse, mutect2, varscan2
- XKR3 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.257); catalogued as rs575515758; called by muse, mutect2
- ZNF232 | c.1136G>T p.R379M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100005822; called by muse, mutect2, varscan2
- ZNF292 | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs756555025, COSV60539842; called by muse, mutect2, varscan2
- IGKV1-5 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PEG10 | c.357_363del p.C119* (on ENST00000482108 / NM_001040152.2; = p.C153* on NM_015068.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | called by mutect2, pindel, varscan2
- TEX15 | c.7454del p.P2485Qfs*12 (on ENST00000256246; = p.P2868Qfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by pindel, varscan2
- TEX15 | c.7448A>T p.N2483I (on ENST00000256246; = p.N2866I on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, varscan2
- UGGT2 | c.605del p.L202Cfs*35 | Frame Shift Del (DEL) | VAF 46/233 reads (20%) | called by mutect2, pindel, varscan2
- C10orf90 | c.927A>C p.L309= | Silent (SNP) | VAF 12/183 reads (7%) | catalogued as COSV99505214; called by muse, mutect2
- CASP8AP2 | c.1881C>T p.T627= | Silent (SNP) | VAF 38/74 reads (51%) | catalogued as COSV99387591; called by muse, varscan2
- CCDC93 | c.399G>A p.E133= | Silent (SNP) | VAF 38/612 reads (6%) | catalogued as rs757971766, COSV100099538; called by muse, mutect2
- COL11A1 | c.1680T>G p.P560= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV62184430; called by muse, mutect2, varscan2
- GABRB3 | c.1266G>A p.P422= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs377621777; called by muse, mutect2, varscan2
- GPC4 | c.663C>T p.F221= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as rs1471389203, COSV63697968; called by muse, mutect2, varscan2
- HIPK4 | c.201T>G p.P67= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as rs1476117542, COSV99397103; called by muse, mutect2
- HJV | c.627G>A p.A209= (on ENST00000336751 / NM_213653.4; = p.A96= on NM_145277.5) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV60952150; called by muse, mutect2, varscan2
- KPRP | c.1575C>G p.T525= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV64221759; called by muse, mutect2, varscan2
- LRP1B | c.2463C>T p.A821= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as rs770657509, COSV67224110; called by muse, mutect2, varscan2
- NDST3 | c.2544G>T p.V848= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV56619570; called by muse, mutect2, varscan2
- PCDHB10 | c.1524G>T p.A508= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53376801, COSV53379221; called by muse, mutect2, varscan2
- PNMA2 | c.316T>C p.L106= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1293764729, COSV72908527; called by muse, mutect2, varscan2
- SULT1C4 | c.237G>A p.R79= | Silent (SNP) | VAF 25/274 reads (9%) | catalogued as COSV99731788, COSV99731873; called by muse, mutect2
- SUSD5 | c.300G>A p.V100= | Silent (SNP) | VAF 179/448 reads (40%) | catalogued as COSV58877912; called by muse, mutect2, varscan2
- TMEM175 | c.618T>C p.F206= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV53279024; called by muse, mutect2, varscan2
- TNPO3 | c.2547C>T p.T849= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs775545486, COSV55281851; called by muse, mutect2, varscan2
- ZNF791 | c.1503C>T p.C501= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs745926170, COSV58480556; called by muse, mutect2, varscan2
- DNAAF3 | c.-45G>A | 5'UTR (SNP) | VAF 23/73 reads (32%) | catalogued as rs1245290777, COSV100845955; called by muse, mutect2, varscan2
- GRIPAP1 | c.2061+23C>G | Intron (SNP) | VAF 32/1298 reads (2%) | catalogued as COSV100904385; called by muse, mutect2
